Gene-level copy-number profile of tumor specimen ALCH-B4X0-TTP1-A from ALCHEMIST case ALCH-B4X0, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 51.0 years (18,641 days).
Specimen ALCH-B4X0-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4fd2e768-1cdd-4aef-a2f2-7908f80a2b54.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4X0-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,230 have no estimate.
https://portal.gdc.cancer.gov/files/67b3be61-c08a-41c4-99fb-3f05de2ac19d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 93; copy number 1: 1,830; copy number 2: 50,618; copy number 3: 3,899; copy number 4: 1,376; copy number 5: 438; copy number 6: 112; copy number 8: 1; copy number 9: 3; copy number 10: 17; copy number 13: 4; copy number 15: 1; copy number 37: 1.

Homozygous deletions (total copy number 0; autosomes only): 93 genes in 30 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:41,478,775–41,484,683, 1 gene: EDN2.
- chr2:2,638,178–2,696,285, 1 gene: AC018685.2.
- chr2:131,492,813–131,533,666, 2 genes: SMPD4BP, CCDC74A.
- chr5:142,310,427–142,326,455, 3 genes (within-gene range 0–2): SPRY4, AC091825.2, AC091825.1.
- chr6:26,896,952–26,898,777, 1 gene (within-gene range 0–2): POM121L6P.
- chr7:51,382,284–51,387,101, 2 genes: CICP17, AC012441.2.
- chr7:130,344,816–130,368,730, 1 gene: CPA5.
- chr8:46,028,804–46,028,892, 1 gene: AC118650.1.
- chr9:87,825,146–87,825,968, 1 gene (within-gene range 0–2): NPAP1P7.
- chr10:77,782,866–77,793,176, 1 gene (within-gene range 0–2): AL450306.1.
- chr11:59,255,360–59,284,033, 3 genes: WARS1P1, SLC25A47P1, AP002358.1.
- chr12:56,222,015–56,258,384, 3 genes: NABP2, SLC39A5, ANKRD52.
- chr12:132,136,594–132,144,319, 1 gene: DDX51.
- chr14:23,376,773–23,408,273, 3 genes: CMTM5, MYH6, MIR208A.
- chr14:102,545,254–102,555,826, 1 gene: LINC02323.
- chr14:104,724,229–104,795,751, 4 genes: ADSS1, SIVA1, AL583722.1, AKT1.
- chr15:21,980,277–21,981,245, 1 gene: OR11J6P.
- chr15:25,169,337–25,241,827, 40 genes (within-gene range 0–2): DMAC1P1, SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39.
- chr15:41,825,099–41,848,155, 4 genes (within-gene range 0–2): AC020659.2, JMJD7, JMJD7-PLA2G4B, PLA2G4B.
- chr15:41,851,913–41,852,029, 1 gene (within-gene range 0–2): RNA5SP393.
- chr16:83,968,632–84,002,776, 1 gene: NECAB2.
- chr17:81,311,270–81,330,674, 1 gene: TMEM105.
- chr19:3,118,665–3,122,128, 2 genes (within-gene range 0–2): AC005262.2, KF456478.1.
- chr19:3,607,247–3,626,815, 2 genes: CACTIN-AS1, CACTIN.
- chr19:42,198,598–42,232,149, 3 genes (within-gene range 0–2): DEDD2, AC006486.3, ZNF526.
- chr19:49,361,783–49,375,116, 1 gene (within-gene range 0–2): DKKL1.
- chr20:3,227,417–3,245,382, 2 genes: SLC4A11, AL109976.1.
- chr22:22,630,065–22,644,473, 3 genes: BCRP4, AC244250.4, POM121L1P.
- chr22:37,469,063–37,486,393, 1 gene: MFNG.
- chr22:46,576,012–46,738,252, 2 genes: GRAMD4, CERK.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 577 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:34,659,564–36,679,362, 62 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr14:41,296,286–42,703,655, 10 genes, copy number 5 (within-gene range 2–5): AL391516.1, AL356596.1, AL121821.3, AL121821.2, AL121821.1, LRFN5, FKBP1BP1, AL445074.1, AL442163.1, AL450442.1.
- chr14:52,111,122–54,902,826, 46 genes, copy number 5: LINC02319, COX5AP2, AL118557.1, PTGDR, AL365475.1, PTGER2, TXNDC16, GPR137C, ERO1A, AL133453.1, PSMC6, STYX, GNPNAT1, AL139317.3, AL139317.5, AL139317.1, AL139317.2, FERMT2, AL139317.4, AL352979.4, AL352979.1, AL352979.3, DDHD1, AL352979.2, AL356020.1, AL365295.1, AL365295.2, AL163953.1, RPS3AP46, LINC02331, AL138479.1, MIR5580, BMP4, AL138479.2, ATP5F1CP1, CDKN3, CNIH1, AL359792.1, GMFB, CGRRF1, SAMD4A, AL133444.1, GCH1, RNU6ATAC9P, MIR4308, FDPSP3.
- chr14:55,748,208–56,427,032, 9 genes, copy number 5: AL355773.1, RPL13AP3, LINC00520, AL163952.1, AL138995.1, PELI2, AL355073.1, AL355073.2, LINC02284.
- chr14:59,595,976–60,323,907, 13 genes, copy number 5: RTN1, MIR5586, AL133299.1, LRRC9, AL157911.1, PCNX4, DHRS7, SCOCP1, PSMA3P1, RPL17P2, AL157756.1, PPM1A, LINC02322.
- chr14:94,104,836–97,789,256, 83 genes, copy number 5–6 (broad region; genes not listed).
- chr15:21,307,749–21,946,641, 36 genes, copy number 6–10: RNU6-1235P, AC060814.4, AC060814.3, LONRF2P4, AC060814.2, CXADRP2, AC060814.1, GRAMD4P6, POTEB3, MIR3118-3, U6, NF1P9, MIR5701-2, AC183088.4, AC183088.2, AC183088.1, LINC02203, AC183088.3, AC135068.6, AC135068.2, AC135068.12, AC135068.11, AC135068.1, AC135068.4, AC135068.5, AC135068.8, AC135068.7, AC135068.9, AC135068.10, AC135068.3, AC134981.1, MIR3118-4, POTEB, RNU6-631P, ZNF519P3, NF1P2.
- chr16:5,239,802–7,713,340, 1 gene, copy number 5 (within-gene range 3–5): RBFOX1.
- chr16:5,596,856–7,431,296, 15 genes, copy number 5 (within-gene range 3–5): LINC01570, MIR8065, AC012175.1, AC009135.2, AC009135.1, AC006112.1, AC007223.1, AC007012.2, AC007012.1, RNU7-99P, RNU6-457P, RNU6-328P, AC022206.1, AC007222.2, AC007222.1.
- chr16:9,355,588–11,527,245, 62 genes, copy number 5 (broad region; genes not listed).
- chr16:13,246,232–13,563,388, 1 gene, copy number 5 (within-gene range 3–5): U91319.1.
- chr16:13,458,326–14,331,067, 16 genes, copy number 5: TMF1P1, U95743.1, ERCC4, RPS26P52, AC010401.1, AC010401.2, LINC02185, LINC02186, MRTFB, AC130650.2, AC130650.1, TVP23CP2, Y_RNA, MIR193BHG, MIR193B, MIR365A.
- chr16:33,802,764–33,810,767, 2 genes, copy number 15–37: IGHV3OR16-12, AC136428.3.
- chr17:81,228,277–81,241,310, 3 genes, copy number 9: TEPSIN, AC027601.1, NDUFAF8.
- chr19:55,576,774–55,580,848, 1 gene, copy number 8: ZNF579.
- chr20:50,888,916–55,075,140, 53 genes, copy number 5–6: ADNP, PSMD10P1, ADNP-AS1, DPM1, MOCS3, AL050404.1, KCNG1, AL121785.1, RPSAP1, NFATC2, MIR3194, ATP9A, AL138807.1, SALL4, LINC01429, RNU6-347P, RNU7-6P, ZFP64, AL109984.1, ERP29P1, LINC01524, AL109610.1, AL049765.2, AL049765.1, MRPS33P4, AL031674.1, AL121902.1, RPL36P1, TSHZ2, RN7SKP184, AL391097.3, AL391097.1, AL391097.2, AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, PFDN4, AL133335.1, DOK5, RNU4ATAC7P, RPL12P4.
- chr20:58,817,132–59,516,039, 24 genes, copy number 5: AL132655.2, MIR296, MIR298, GNAS-AS1, AL132655.1, GNAS, AL132655.7, AL132655.6, AL132655.4, AL132655.5, AL121917.1, AL121917.2, NELFCD, CTSZ, TUBB1, ATP5F1E, PRELID3B, MRPS16P2, ZNF831, EDN3, AL035250.1, AL035250.2, PIEZO1P1, AL389889.1.
- chr20:61,953,469–64,327,972, 136 genes, copy number 5–10 (broad region; genes not listed).
- chr21:43,414,483–43,479,534, 4 genes, copy number 13: SIK1, LINC00319, LINC00313, AP001048.1.

Autosomal genes at a single copy (total copy number 1): 1,830. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
